Somatic mutation profile of tumor specimen TCGA-AR-A1AO-01A (aliquot TCGA-AR-A1AO-01A-11D-A12Q-09) from TCGA case TCGA-AR-A1AO, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.5 years (17,332 days).
Specimen TCGA-AR-A1AO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a08c7a1e-e8e8-4cbf-b3e6-4bc88e943b05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AO-10A (Blood Derived Normal), aliquot TCGA-AR-A1AO-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/436569b1-7939-451d-9998-9208faf4694a

The open-access MAF lists 78 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 16, Nonsense Mutation 3, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 10/219 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV57246387, COSV57246465, COSV57253558; called by muse, mutect2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 13/160 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCA9 | c.3960A>C p.E1320D | Missense Mutation (SNP) | VAF 32/515 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100383573; called by muse, mutect2
- ADGRL2 | c.544A>T p.T182S | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.842); catalogued as COSV99591840; called by muse, mutect2
- AKNA | c.2563A>C p.M855L | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99801144; called by muse, mutect2
- ANKRD30A | c.1872A>C p.E624D (on ENST00000611781; = p.E568D on NM_052997.2) | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.191); catalogued as COSV100654538; called by muse, mutect2
- ATP11B | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100018165; called by muse, mutect2
- BORA | c.1337C>A p.T446K (on ENST00000613797; = p.T371K on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV100909781; called by muse, mutect2
- CBFA2T2 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 12/237 reads (5%) | catalogued as COSV100656551; called by muse, mutect2
- CDH23 | c.2425G>C p.E809Q | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.169); catalogued as CM1413493, COSV99824183; called by muse, mutect2
- CDK11B | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100478316; called by muse, mutect2
- CLTC | c.3610C>A p.R1204S | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV52252473, COSV99292985; called by muse, mutect2
- COL4A2 | c.2884G>A p.G962S | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847508; called by muse, mutect2
- CSMD3 | c.4874T>C p.V1625A (on ENST00000297405 / NM_001363185.1; = p.V1521A on NM_052900.3) | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV99849735; called by muse, mutect2
- CXorf58 | c.613C>A p.R205S | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101003125, COSV64858528; called by muse, mutect2
- DCAF10 | c.1674G>C p.K558N | Missense Mutation (SNP) | VAF 17/451 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99647949; called by muse, mutect2
- DCX | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs146279155, COSV100576793; called by muse, mutect2
- DOCK4 | c.216A>T p.K72N | Missense Mutation (SNP) | VAF 18/417 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV101455855; called by muse, mutect2
- EDEM1 | c.1643G>C p.S548T | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99849448; called by muse, mutect2
- FKBP15 | c.1768G>C p.E590Q | Missense Mutation (SNP) | VAF 69/686 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99440068; called by muse, mutect2, varscan2
- FLNA | c.7471G>T p.A2491S (on ENST00000369850 / NM_001110556.2; = p.A2483S on NM_001456.3) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as COSV100775321; called by muse, mutect2
- FOXA1 | c.1202C>A p.S401Y | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51648283; called by muse, mutect2
- GRIN2D | c.2542G>A p.V848I | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV53520526; called by muse, mutect2, varscan2
- GRK7 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 18/303 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99380350; called by muse, mutect2
- GRM3 | c.316T>G p.L106V | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100862960; called by muse, mutect2
- HIVEP2 | c.4483C>A p.L1495M | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV99175883; called by muse, mutect2
- HUWE1 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 12/124 reads (10%) | catalogued as COSV99474538; called by muse, mutect2
- LILRA5 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as COSV56644993; called by muse, mutect2
- LRP2 | c.12619G>C p.E4207Q | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.027); catalogued as COSV55554236, COSV99790515; called by muse, mutect2
- LRRC8A | c.1789G>C p.E597Q | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV99396570; called by muse, mutect2
- LSG1 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99503580; called by muse, mutect2
- MAST4 | c.2416G>A p.D806N (on ENST00000403625 / NM_001164664.2; = p.D617N on NM_015183.3) | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1401126305, COSV99846150; called by muse, mutect2
- MEFV | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99561396; called by muse, mutect2
- MTA2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 28/479 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs377599047, COSV53870243; called by muse, mutect2
- MTTP | c.2207A>G p.D736G | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99645651; called by muse, mutect2
- MUC17 | c.9877G>C p.V3293L | Missense Mutation (SNP) | VAF 54/625 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.785); catalogued as COSV100075314; called by muse, mutect2
- MYLK | c.4709C>T p.S1570L | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.117); catalogued as rs747368032, COSV100659748; called by muse, mutect2
- MYO7B | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 24/441 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101268409, COSV67351296; called by muse, mutect2
- NCAM2 | c.1928A>C p.K643T | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as COSV53060661, COSV99525608; called by muse, mutect2
- NUP153 | c.3365C>A p.A1122D | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV100020909, COSV50446053; called by muse, mutect2
- PLCXD2 | c.24G>T p.R8S | Missense Mutation (SNP) | VAF 26/289 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as COSV101210147, COSV67341524; called by muse, mutect2
- PPP1R1C | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as COSV99724424; called by muse, mutect2
- RPS25 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 48/785 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV100548941; called by muse, mutect2
- RRN3 | c.376G>C p.V126L | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as rs1487000356; called by muse, mutect2
- SELENOP | c.366T>G p.D122E | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100736927; called by muse, mutect2
- SH2D3A | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs757778461, COSV55588336; called by muse, mutect2, varscan2
- SLC24A1 | c.1709T>G p.I570R | Missense Mutation (SNP) | VAF 112/912 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV56053754; called by muse, mutect2, varscan2
- SPEN | c.7201G>A p.D2401N | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.679); catalogued as COSV65360028; called by muse, mutect2
- SPTA1 | c.4478G>A p.R1493Q | Missense Mutation (SNP) | VAF 15/297 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); catalogued as rs544007770, COSV63755443, COSV63760682; called by muse, mutect2
- SPZ1 | c.984C>A p.C328* | Nonsense Mutation (SNP) | VAF 15/160 reads (9%) | catalogued as COSV99698287; called by muse, mutect2, varscan2
- SRBD1 | c.402A>C p.K134N | Missense Mutation (SNP) | VAF 66/861 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99765637; called by muse, mutect2
- STXBP3 | c.24G>C p.R8S | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.121); catalogued as COSV99601809; called by muse, mutect2
- SUOX | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV99907237; called by muse, mutect2
- TDRD10 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99427734; called by muse, mutect2
- TRPC3 | c.2563C>G p.L855V (on ENST00000379645 / NM_001366479.2; = p.L782V on NM_003305.2) | Missense Mutation (SNP) | VAF 34/558 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV99313576; called by muse, mutect2
- UVRAG | c.1643C>G p.S548C | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV100638675; called by muse, mutect2
- VEPH1 | c.1468G>C p.D490H | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV100748098; called by muse, mutect2
- WDR72 | c.674A>G p.E225G | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100855168; called by muse, mutect2, varscan2
- ZZZ3 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1368052794, COSV100890468; called by muse, mutect2
- RBMXL2 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2
- ADAM19 | c.2142G>A p.L714= | Silent (SNP) | VAF 34/531 reads (6%) | catalogued as COSV99978615; called by muse, mutect2
- ATXN7 | c.2505G>A p.K835= | Silent (SNP) | VAF 16/266 reads (6%) | catalogued as rs767157386, COSV99894214, COSV99895458; called by muse, mutect2
- CENPS-CORT | c.15G>A p.A5= | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as rs1018281226, COSV100471888; called by muse, mutect2
- CYP1A1 | c.90A>G p.R30= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV65698046; called by muse, mutect2, varscan2
- DNAJC5B | c.288C>T p.D96= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as rs1421434526, COSV99396009; called by muse, mutect2
- ERP29 | c.540C>G p.L180= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV55674426; called by muse, mutect2, varscan2
- GTF3C2 | c.939C>A p.L313= | Silent (SNP) | VAF 25/438 reads (6%) | catalogued as COSV99273335; called by muse, mutect2
- NRDE2 | c.2905C>T p.L969= | Silent (SNP) | VAF 35/257 reads (14%) | catalogued as COSV62964316; called by muse, mutect2, varscan2
- NT5C1A | c.156C>G p.V52= | Silent (SNP) | VAF 10/171 reads (6%) | catalogued as COSV99348705; called by muse, mutect2
- PCDH19 | c.471C>T p.D157= | Silent (SNP) | VAF 10/141 reads (7%) | catalogued as COSV99720877; called by muse, mutect2
- RYR3 | c.13425C>A p.T4475= (on ENST00000389232; = p.T4476= on NM_001036.6) | Silent (SNP) | VAF 22/342 reads (6%) | catalogued as COSV101214868; called by muse, mutect2
- SETDB1 | c.1197C>T p.F399= | Silent (SNP) | VAF 21/318 reads (7%) | catalogued as COSV99645977; called by muse, mutect2
- SUOX | c.27C>T p.V9= | Silent (SNP) | VAF 17/269 reads (6%) | catalogued as rs1162056451, COSV99907235; called by muse, mutect2
- SUPT7L | c.210T>A p.I70= | Silent (SNP) | VAF 32/530 reads (6%) | catalogued as COSV100389692; called by muse, mutect2
- SYNE2 | c.18879T>C p.I6293= | Silent (SNP) | VAF 10/178 reads (6%) | catalogued as rs1479822805, COSV100648566; called by muse, mutect2
- THSD7B | c.414G>A p.L138= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as rs774628204, COSV99758810; called by muse, mutect2
- PKD1L2 | n.3190C>G | RNA (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- SSPOP | n.12230G>A | RNA (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100948148; called by muse, mutect2
